MMRF case MMRF_2267 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c432cc3c-220f-4e5e-b296-f642b0f0c042

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 79 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.4 years (28,984 days); ISS stage: III; Days to last known disease status: 845 days (2.3 years); Days to last follow up: 845 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 58 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 23 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 62 days; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 72 days; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 155 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 155 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 624 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 7.79 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 5.84 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 81.3 µmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 4.84 mmol/L.
- Day 104 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 14.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.34 mg/dL; Immunoglobulin G 5.1 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 4.24 mmol/L.
- Day 215 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 8.91 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 3.55 µg/mL; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 5.78 mmol/L.
- Day 275 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 5.29 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 5.8 g/dL; Glucose 6.99 mmol/L.
- Day 335 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 5.7 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 3.12 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 405 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 5.69 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.34 mmol/L.
- Day 492 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 5.85 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.28 mmol/L.
- Day 572 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 5.53 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 7.43 mmol/L.
- Day 663 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 7.27 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.85 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 754 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 5.05 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.51 mmol/L.
- Day 845 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 6.01 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.6 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day -5: Weight: 69 kg; Height: 154 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2267_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2267_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
